Gene-level copy-number profile of tumor specimen TCGA-04-1649-01A from TCGA case TCGA-04-1649, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.4 years (27,165 days).
Specimen TCGA-04-1649-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2a358871-990f-478b-ab36-a50f66506f0e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1649-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e5efb42-35d3-456b-a613-624328030318

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,010; copy number 2: 22,032; copy number 3: 16,040; copy number 4: 13,780; copy number 5: 4,744; copy number 6: 187; copy number 7: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1649-01A-01D-0577-01): tumor purity 0.71, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,947 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,466,937–62,178,675, 489 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:64,745,095–68,202,987, 58 genes, copy number 5 (within-gene range 4–5): RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, AL513493.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P, SGIP1, MIR3117, AL139147.1, TCTEX1D1, INSL5, DNAI4, AL592161.1, MIER1, SLC35D1, C1orf141, AL133320.1, AL133320.2, IL23R, RNU6-586P, RNU4ATAC4P, DNAJB6P4, IL12RB2, SERBP1, RNU6-387P, LINC01702, RNU6-1031P, AL590559.1, RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P, GNG12-AS1, AL157407.1, DIRAS3, ARL5AP3.
- chr1:74,568,117–75,123,927, 7 genes, copy number 6 (within-gene range 4–6): ERICH3, ERICH3-AS1, AC135803.1, CRYZ, TYW3, AC133865.1, AC099786.3.
- chr1:111,250,254–111,716,691, 22 genes, copy number 6 (within-gene range 4–6): CHIAP1, CHIAP2, CHIA, AL356387.1, AL356387.2, PIFO, CHIAP3, HIGD1AP12, PGBP, OVGP1, AL390195.2, UBE2FP3, AL390195.1, WDR77, Y_RNA, ATP5PB, C1orf162, TMIGD3, RNU6-792P, ADORA3, RAP1A, LINC01160.
- chr1:155,120,490–248,919,946, 2,077 genes, copy number 5–6 (broad region; genes not listed).
- chr2:113,022,089–113,278,921, 9 genes, copy number 5 (within-gene range 4–5): IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8.
- chr3:54,122,547–55,505,261, 13 genes, copy number 5 (within-gene range 3–5): CACNA2D3, RPS15P5, ESRG, CACNA2D3-AS1, LRTM1, AC092059.1, LINC02017, LINC02030, AC121764.2, AC121764.3, WNT5A, WNT5A-AS1, AC121764.1.
- chr3:55,610,603–55,852,594, 3 genes, copy number 5: AC025572.1, ERC2-IT1, MIR3938.
- chr3:107,834,586–107,928,907, 1 gene, copy number 5 (within-gene range 4–5): LINC00636.
- chr3:108,032,456–108,138,610, 3 genes, copy number 5: AC012020.1, CD47, LINC01215.
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr6:12,406,486–14,231,570, 27 genes, copy number 5: RN7SKP293, RPL15P3, LINC02530, PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1.
- chr6:15,522,195–15,663,058, 3 genes, copy number 7: 5S_rRNA, DTNBP1, AL021978.1.
- chr6:16,041,381–16,205,120, 8 genes, copy number 7: AL365265.1, MDH1P2, MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P.
- chr6:19,143,695–21,232,404, 25 genes, copy number 5 (within-gene range 3–5): AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P.
- chr6:131,135,467–131,283,535, 1 gene, copy number 5 (within-gene range 3–5): AKAP7.
- chr6:131,469,059–131,628,242, 3 genes, copy number 5 (within-gene range 3–5): RPL21P67, ARG1, MED23.
- chr7:131,500,262–131,702,653, 5 genes, copy number 7 (within-gene range 4–7): PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2.
- chr10:44,712–14,462,142, 249 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:14,652,689–16,295,858, 30 genes, copy number 5: AL158168.1, RNA5SP302, RPSAP7, CDNF, AC069544.2, HSPA14, AC069544.1, SUV39H2, DCLRE1C, MEIG1, OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1, OLAH, ACBD7, GAPDHP45, RPP38-DT, RPP38, NMT2, PPIAP30, AL590365.1, FAM171A1, AL607028.1, ITGA8, MINDY3, AL358033.1, FTLP19, RNU6-1075P, LINC02654.
- chr11:34,430,880–34,743,199, 8 genes, copy number 5: CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1.
- chr11:68,008,578–83,423,516, 398 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:121,238,304–121,633,763, 7 genes, copy number 6 (within-gene range 4–6): AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1.
- chr14:68,113,706–68,422,196, 6 genes, copy number 5: AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6.
- chr19:17,452,211–21,594,628, 209 genes, copy number 5 (broad region; genes not listed).
- chr19:23,919,081–23,958,035, 1 gene, copy number 5 (within-gene range 4–5): AC011503.1.
- chr19:24,004,358–30,713,538, 73 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:31,787,148–41,428,730, 458 genes, copy number 5 (broad region; genes not listed).
- chr20:46,484,461–47,656,877, 26 genes, copy number 5: ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1.
- chr20:47,677,901–47,686,297, 1 gene, copy number 5: AL354813.1.
- chr21:32,259,804–32,625,096, 17 genes, copy number 5: AP000265.1, MIS18A, MIS18A-AS1, MRAP, MRAP-AS1, URB1, SNORA80A, URB1-AS1, CFAP298-TCP10L, EVA1C, EXOSC3P1, TCP10L, AP000272.1, RNA5SP490, CFAP298, OR7E23P, AP000275.1.

Autosomal genes at a single copy (total copy number 1): 3,010. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
